Somatic mutation profile of tumor specimen TARGET-30-PATGLU-01A (aliquot TARGET-30-PATGLU-01A-01D) from TARGET case TARGET-30-PATGLU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,037 days).
Specimen TARGET-30-PATGLU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26339556-6f3a-4b04-bb51-6a5e67773b73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATGLU-10A (Blood Derived Normal), aliquot TARGET-30-PATGLU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4063c9f-b8dc-420f-8f3c-2f5644b7a77a

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.10087G>T p.V3363L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60911699; called by muse, mutect2, varscan2
- CYP21A2 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64476222; called by mutect2, varscan2
- ELOVL3 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as rs140986921, COSV64174253; called by muse, mutect2, varscan2
- HCRTR2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.044); catalogued as rs201320094, COSV63794768; called by muse, mutect2, varscan2
- IGSF10 | c.7802G>T p.G2601V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56373764; called by muse, mutect2, varscan2
- NLRP3 | c.2000G>T p.C667F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV60221999; called by muse, mutect2, varscan2
- OR1S1 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV58706620; called by muse, mutect2, varscan2
- SLC44A5 | c.432C>G p.D144E | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63761615; called by muse, mutect2, varscan2
- SSTR2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV59535065; called by muse, mutect2, varscan2
- TBC1D22B | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1048431880, COSV65142547; called by muse, mutect2, varscan2
- EEF1AKNMT | c.352G>C p.V118L (on ENST00000361735 / NM_015935.5; = p.V32L on NM_014955.3) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); called by muse, mutect2
- CPEB1 | c.864G>T p.G288= (on ENST00000617958; = p.G228= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55617996, COSV99918046; called by muse, mutect2, varscan2
- KRT4 | c.945C>T p.Y315= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs778125368, COSV53406546; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBE1 | c.1281T>C p.H427= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV57889036; called by muse, mutect2, varscan2
